Somatic mutation profile of tumor specimen TCGA-DU-8168-01A (aliquot TCGA-DU-8168-01A-11D-2253-08) from TCGA case TCGA-DU-8168, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 55.1 years (20,136 days).
Specimen TCGA-DU-8168-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e36918f0-9839-4722-b068-5a31319860e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-8168-10A (Blood Derived Normal), aliquot TCGA-DU-8168-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32ba9e1f-c416-4bcc-a52e-b4fcf87dfc23

The open-access MAF lists 66 somatic variants for this specimen: 48 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 35, Silent 18, In Frame Del 7, Frame Shift Del 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 52/111 reads (47%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NOTCH1 | c.1070_1072del p.F357del | In Frame Del (DEL) | VAF 6/16 reads (38%) | hotspot (GDC flag); called by mutect2, varscan2
- PIK3CA | c.328_330del p.E110del | In Frame Del (DEL) | VAF 34/84 reads (40%) | hotspot (GDC flag); called by pindel, varscan2
- AKAP13 | c.6095A>C p.Q2032P (on ENST00000394518 / NM_007200.5; = p.Q2036P on NM_006738.6) | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.372); catalogued as COSV63459132; called by muse, mutect2, varscan2
- ARHGAP11A | c.2708A>G p.Q903R | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV55706597; called by muse, mutect2, varscan2
- ATXN3L | c.512A>G p.D171G | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV66075750; called by muse, mutect2, varscan2
- BFSP2 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0.05); catalogued as COSV56589111; called by muse, mutect2, varscan2
- CASK | c.2317C>A p.H773N (on ENST00000378163 / NM_001367721.1; = p.H768N on NM_003688.3) | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59367431; called by muse, mutect2, varscan2
- CHRNB3 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 9/233 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51495305; called by muse, mutect2
- CSF2RA | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 98/308 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.046); catalogued as rs147180621, COSV62624881; called by muse, mutect2, varscan2
- D2HGDH | c.1328A>G p.N443S | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs149519095; called by muse, mutect2, varscan2
- DEGS1 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 7/177 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60378976, COSV60379364; called by muse, mutect2
- FANK1 | c.158A>G p.D53G | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64156580; called by muse, mutect2, varscan2
- GLRA1 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.426); catalogued as rs561848502, COSV51007409; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- HGF | c.803G>A p.R268K | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.303); catalogued as COSV55950439; called by muse, mutect2, varscan2
- LIG3 | c.2375C>T p.S792L | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as rs1225851538, COSV52007975; called by muse, mutect2, varscan2
- MAGEE1 | c.1535T>C p.I512T | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV63910468; called by muse, mutect2, varscan2
- MAPK8IP3 | c.926G>T p.R309L | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.194); catalogued as COSV51721024; called by muse, mutect2, varscan2
- MGAT4C | c.1175T>A p.I392N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59833204; called by muse, mutect2
- MUC16 | c.28609C>A p.P9537T | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.07); catalogued as COSV67469592; called by muse, mutect2
- MUC2 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 88/182 reads (48%) | SIFT tolerated (0.14); catalogued as rs267602687; called by muse, mutect2, varscan2
- NLRP14 | c.2708C>T p.T903M | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.078); catalogued as rs376413939; called by muse, mutect2
- OR2T4 | c.683A>T p.E228V | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63544121; called by muse, mutect2, varscan2
- PLXND1 | c.3335C>T p.T1112M | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as rs146029556; called by muse, mutect2, varscan2
- POLR3A | c.1518C>A p.N506K | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64931126; called by muse, mutect2, varscan2
- PREX2 | c.2280C>A p.S760R | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.258); catalogued as COSV55773546; called by muse, mutect2, varscan2
- PRR23B | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as rs780923964, COSV61494016; called by muse, mutect2, varscan2
- PTPRJ | c.1292A>G p.N431S | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.262); catalogued as rs561061051, COSV69252502; called by muse, mutect2, varscan2
- SAP30 | c.289_291del p.K97del | In Frame Del (DEL) | VAF 31/73 reads (42%) | catalogued as rs761907667; called by pindel, varscan2
- SOX17 | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52024815; called by muse, varscan2
- TAB1 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV53371579; called by muse, mutect2, varscan2
- THBS4 | c.92T>G p.F31C | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs1366305170, COSV63469523; called by muse, mutect2, varscan2
- TIMELESS | c.119G>C p.R40P | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57511835, COSV99974232; called by muse, mutect2
- UNC45B | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52096273; called by muse, mutect2, varscan2
- ZBTB39 | c.626C>T p.T209I | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as rs201184273, COSV55629535; called by muse, mutect2, varscan2
- ZCCHC12 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 61/95 reads (64%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs946147207, COSV59570945; called by muse, mutect2, varscan2
- ZNF208 | c.2516G>A p.G839D | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV68107013; called by muse, mutect2, varscan2
- ZNF442 | c.857C>A p.T286N | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.919); catalogued as COSV54421627; called by muse, mutect2
- CIC | c.2674_2675del p.V892Tfs*38 | Frame Shift Del (DEL) | VAF 40/65 reads (62%) | called by mutect2, pindel, varscan2
- DMXL1 | c.2440_2442del p.I814del | In Frame Del (DEL) | VAF 118/336 reads (35%) | called by pindel, varscan2
- FUBP1 | c.262_263del p.Q88Vfs*33 | Frame Shift Del (DEL) | VAF 26/44 reads (59%) | called by pindel, varscan2
- HDAC2 | c.323_324del p.F108* | Frame Shift Del (DEL) | VAF 15/87 reads (17%) | called by mutect2, pindel, varscan2
- HSD17B4 | c.308_310del p.E103del (on ENST00000414835 / NM_001199291.3; = p.E78del on NM_000414.4 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 66/162 reads (41%) | called by pindel, varscan2
- ITGAM | c.3400_3402del p.F1134del (on ENST00000648685 / NM_001145808.2; = p.F1133del on NM_000632.4) | In Frame Del (DEL) | VAF 4/21 reads (19%) | called by pindel, varscan2
- NOTCH1 | c.1391_1393del p.D464del | In Frame Del (DEL) | VAF 20/124 reads (16%) | called by pindel, varscan2
- PBRM1 | c.1454_1457del p.K485Sfs*14 | Frame Shift Del (DEL) | VAF 23/44 reads (52%) | called by pindel, varscan2
- TSPYL4 | c.977_980del p.L326Pfs*38 | Frame Shift Del (DEL) | VAF 7/71 reads (10%) | called by mutect2, pindel, varscan2
- WDFY3 | c.3451_3454del p.I1151Ffs*48 | Frame Shift Del (DEL) | VAF 52/177 reads (29%) | called by mutect2, pindel, varscan2
- C16orf86 | c.444A>G p.P148= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs372390098; called by muse, mutect2, varscan2
- CACNA1E | c.3570C>T p.D1190= | Silent (SNP) | VAF 10/279 reads (4%) | catalogued as COSV62398193; called by muse, mutect2
- CCNB3 | c.615G>A p.A205= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as rs373752549, COSV52070828; called by muse, mutect2, varscan2
- CENPU | c.108A>G p.Q36= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV55657871; called by muse, mutect2, varscan2
- DNAH1 | c.8655G>A p.R2885= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV70229573; called by muse, mutect2, varscan2
- DPEP2 | c.384C>T p.G128= | Silent (SNP) | VAF 53/130 reads (41%) | catalogued as rs151283462; called by muse, mutect2, varscan2
- DSG1 | c.2580A>G p.S860= | Silent (SNP) | VAF 19/229 reads (8%) | catalogued as COSV57136010; called by muse, mutect2
- DSP | c.5859C>A p.T1953= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as COSV65793125; called by muse, mutect2, varscan2
- FAM90A1 | c.153C>T p.G51= | Silent (SNP) | VAF 44/99 reads (44%) | catalogued as rs77163560, COSV56712377; called by muse, mutect2, varscan2
- IGHV3-48 | c.63G>T p.V21= | Silent (SNP) | VAF 24/141 reads (17%) | catalogued as rs542582594; called by muse, varscan2
- KDM4B | c.1656G>A p.E552= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV50223183, COSV50266918; called by muse, mutect2, varscan2
- MED23 | c.2853T>C p.Y951= | Silent (SNP) | VAF 20/189 reads (11%) | catalogued as COSV63432890; called by muse, mutect2, varscan2
- NDST1 | c.2307C>T p.H769= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs768728267, COSV55787757; called by muse, mutect2, varscan2
- SEC14L1 | c.1710G>A p.S570= | Silent (SNP) | VAF 153/387 reads (40%) | catalogued as rs202169419, COSV66722565, COSV66725771; called by muse, mutect2, varscan2
- SERPINB2 | c.1227C>T p.F409= | Silent (SNP) | VAF 42/96 reads (44%) | catalogued as rs371265633; called by muse, mutect2, varscan2
- TANC1 | c.3066T>C p.T1022= | Silent (SNP) | VAF 63/142 reads (44%) | catalogued as COSV55088958; called by muse, mutect2, varscan2
- TMEM71 | c.246C>T p.C82= | Silent (SNP) | VAF 79/196 reads (40%) | catalogued as rs183699304, COSV63456526; called by muse, mutect2, varscan2
- ZMIZ2 | c.1020C>T p.G340= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as rs756330810, COSV54808632; called by muse, mutect2, varscan2
